Somatic mutation profile of cancer-model specimen HCM-CSHL-0837-D01-85P (3D Organoid, passage 9; aliquot HCM-CSHL-0837-D01-85P-01D-A85L-36), derived from the premalignant tumor of HCMI case HCM-CSHL-0837-D01, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Intraductal papillary-mucinous carcinoma, non-invasive; Tissue or organ of origin: Pancreas, NOS; Tumor grade: GX; Age at diagnosis: 67.7 years (24,735 days).
Specimen HCM-CSHL-0837-D01-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a42d3c5-9305-4d0b-b2d7-1c5618906dcf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0837-D01-10A (Blood Derived Normal), aliquot HCM-CSHL-0837-D01-10A-01D-A85L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66348d17-791a-44d6-9285-4e52fe6df194

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Nonsense Mutation 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 154/336 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- COL12A1 | c.6055C>T p.Q2019* | Nonsense Mutation (SNP) | VAF 16/292 reads (5%) | catalogued as COSV59399324; called by muse, mutect2
- EMG1 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 165/291 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782511052; called by muse, mutect2, varscan2
- EPHA1 | c.1442A>G p.Y481C | Missense Mutation (SNP) | VAF 132/274 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769207409; called by muse, mutect2, varscan2
- PCDHGA10 | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 181/415 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as rs372466798, COSV53923930; called by muse, mutect2, varscan2
- SGO2 | c.2989A>G p.I997V | Missense Mutation (SNP) | VAF 98/212 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs370969829; called by muse, mutect2, varscan2
- SHCBP1L | c.1930G>A p.V644I | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.034); catalogued as rs905396561; called by muse, mutect2, varscan2
- WDFY4 | c.6632G>A p.R2211Q | Missense Mutation (SNP) | VAF 113/212 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as rs765669221, COSV55425902; called by muse, mutect2, varscan2
- CFAP74 | c.1695del p.F566Lfs*22 | Frame Shift Del (DEL) | VAF 116/302 reads (38%) | called by mutect2, pindel, varscan2
- COL6A5 | c.3355C>A p.P1119T | Missense Mutation (SNP) | VAF 154/296 reads (52%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- MAP2K7 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 254/255 reads (100%) | called by muse, mutect2, varscan2
- MEMO1 | c.131C>G p.A44G | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- PGLYRP3 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 98/170 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC2A4RG | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 214/418 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- TBC1D12 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 191/408 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- VAC14 | c.707G>A p.C236Y | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZBED3 | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 188/382 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNG3 | c.189G>T p.L63= | Silent (SNP) | VAF 107/229 reads (47%) | called by muse, mutect2, varscan2
- MUC16 | c.10257G>A p.V3419= | Silent (SNP) | VAF 31/411 reads (8%) | called by muse, mutect2
- TTLL10 | c.1104G>A p.P368= (on ENST00000379289 / NM_001130045.2; = p.P295= on NM_153254.3) | Silent (SNP) | VAF 146/300 reads (49%) | catalogued as rs371622937; called by muse, mutect2, varscan2
- USP6 | c.1029G>A p.R343= | Silent (SNP) | VAF 114/241 reads (47%) | catalogued as rs768000321; called by muse, mutect2, varscan2
- RIC8B | c.1452-11413G>A | Intron (SNP) | VAF 105/225 reads (47%) | called by muse, mutect2, varscan2
